Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4J9, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4J9-01A (Primary Tumor).

Gross Description: Stomach with the plate-like tumor up to 7 x 6.5 cm in size, with invasion into the muscle layer. Fatty tissue of the greater and lesser curvature and omentum are of normal structure.

Microscopic Description: Adenocarcinoma of the stomach, G-3, with intra- and extracellular mucin production, with invasion of the whole wall thickness. Fatty tissue of the greater and lesser curvature and omentum demonstrates hyperemia.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Subserosa, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Antrum

Tumor size: 6.5 x 0 x 7 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Subserosa

Lymph nodes: 0/10 positive for metastasis (Greater and lesser curvature and omentum 0/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

1C8-0-3

adenocarcinoma, NOS 8140/3

Site: stomach, antrum C16.3

hw 10/2/12

Source: NCI Genomic Data Commons file 752aa97e-76f4-43fb-b900-f4e5aa7c1ecc (TCGA-BR-A4J9.9D2BB6EC-782D-4132-B51A-92ADDC975360.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).